Somatic mutation profile of tumor specimen TCGA-DX-A23V-01A (aliquot TCGA-DX-A23V-01A-11D-A29N-09) from TCGA case TCGA-DX-A23V, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 57.9 years (21,155 days).
Specimen TCGA-DX-A23V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91772bfb-bdaa-457b-bde4-cb0ba1d234d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A23V-10A (Blood Derived Normal), aliquot TCGA-DX-A23V-10A-01D-A29N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e73a6417-7b74-484c-b0e1-0506c50c973f

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANAPC2 | c.1660A>G p.M554V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as rs771131725, COSV100118984; called by muse, mutect2, varscan2
- B4GALNT1 | c.852G>T p.K284N | Missense Mutation (SNP) | VAF 62/730 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1312553, COSV100247036; called by muse, mutect2
- PKHD1 | c.10858C>T p.R3620C | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs557405366, COSV64385526; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SATB2 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.808); catalogued as COSV99610958; called by muse, mutect2, varscan2
- SREBF1 | c.1003T>C p.Y335H | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99888638; called by muse, mutect2, varscan2
- TEX13A | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100781098; called by muse, mutect2, varscan2
- TRPV4 | c.2269C>T p.R757C | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757814511, COSV99924572; called by muse, mutect2, varscan2
- ZNF479 | c.439C>A p.Q147K | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); catalogued as rs782236736, COSV100482659; called by muse, mutect2, varscan2
- ZNF880 | c.725G>A p.C242Y | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs764274378, COSV101424944; called by muse, mutect2, varscan2
- AP2A1 | c.1287C>T p.A429= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs770288996, COSV100756226; called by muse, mutect2, varscan2
- GBP7 | c.277C>T p.L93= | Silent (SNP) | VAF 152/204 reads (75%) | catalogued as COSV99643011; called by muse, mutect2, varscan2
- KLHL6 | c.1305C>T p.I435= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV100384499, COSV58069151; called by muse, mutect2, varscan2
- PPARA | c.198G>C p.S66= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs369963518, COSV99415361; called by muse, mutect2, varscan2
- MFRP | chr11:119345850 G>T | 5'Flank (SNP) | VAF 29/52 reads (56%) | catalogued as COSV100793389, COSV64128791; called by muse, mutect2, varscan2
